Somatic mutation profile of tumor specimen MP2PRT-PAVWGC-TBP1-A (aliquot MP2PRT-PAVWGC-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVWGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,585 days).
Specimen MP2PRT-PAVWGC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a85b84f0-3a49-42a5-9483-4c7054f93671.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWGC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWGC-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23c8aa30-dd0e-4582-8e69-86869c766b9a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Del 2, Silent 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.707C>T p.S236L (on ENST00000219054; = p.S157L on NM_001308169.2) | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs142316126; called by muse, mutect2, varscan2
- IGKV2D-24 | c.360del p.P120del | Frame Shift Del (DEL) | VAF 54/251 reads (22%) | catalogued as rs769705794; called by mutect2, pindel, varscan2
- WNK4 | c.1863G>A p.S621= | Splice Region (SNP) | VAF 111/395 reads (28%) | catalogued as rs768940964; called by muse, mutect2, varscan2
- ACSM2B | c.1179G>A p.Q393= | Splice Region (SNP) | VAF 64/248 reads (26%) | called by muse, mutect2
- FO393400.1 | c.786G>T p.L262F | Missense Mutation (SNP) | VAF 55/235 reads (23%) | called by muse, mutect2, varscan2
- SH3BP4 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRHDE | c.716del p.A239Gfs*94 | Frame Shift Del (DEL) | VAF 164/348 reads (47%) | called by mutect2, varscan2
- SPHKAP | c.1518G>T p.V506= | Silent (SNP) | VAF 168/363 reads (46%) | called by muse, mutect2, varscan2
- TRMT11 | c.972G>A p.K324= | Silent (SNP) | VAF 66/284 reads (23%) | catalogued as rs1441486348; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.-389G>A | 5'UTR (SNP) | VAF 122/470 reads (26%) | catalogued as rs181705524; called by muse, mutect2, varscan2
